Somatic mutation profile of tumor specimen MMRF_1647_1_BM_CD138pos (aliquot MMRF_1647_1_BM_CD138pos_T2_KBS5U_K11920) from MMRF case MMRF_1647, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 81.0 years (29,589 days).
Specimen MMRF_1647_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0f0a155-b987-4b4a-8fe0-c2f2be7dbacb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1647_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1647_1_PB_Whole_C7_KBS5U_K11911; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08fed22c-8215-4824-a51f-999b400fcad5

The open-access MAF lists 43 somatic variants for this specimen: 19 protein-altering or splice-affecting, 11 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 11, 3'UTR 6, Intron 5, Frame Shift Ins 1, Nonsense Mutation 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTG1 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.09); catalogued as rs199524509; called by muse, mutect2, varscan2
- KLHL6 | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 18/81 reads (22%) | catalogued as rs745834978, COSV58065653, COSV58069055; called by muse, mutect2, varscan2
- KRT34 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs866265957, COSV101222713, COSV67449443; called by muse, mutect2
- KRT5 | c.1120C>T p.R374W | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs758181003; called by muse, mutect2, varscan2
- MICAL2 | c.2357C>T p.T786M | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.006); catalogued as rs200663760; called by muse, mutect2, varscan2
- OBSCN | c.13375G>A p.V4459M | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs1266647266; called by muse, mutect2
- OR4N2 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs770622276, COSV60050519; called by muse, mutect2, varscan2
- PPP1R21 | c.89G>A p.G30D | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54288779; called by muse, mutect2, varscan2
- RITA1 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 53/281 reads (19%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs538504098, COSV55320521; called by muse, mutect2, varscan2
- CLSPN | c.1071C>A p.N357K | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- IGKJ5 | c.9_12dup p.Q6Rfs*9 | Frame Shift Ins (INS) | VAF 20/132 reads (15%) | called by pindel, varscan2
- KDM2B | c.1793C>T p.A598V | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.202); called by muse, mutect2
- PBRM1 | c.4822G>A p.E1608K (on ENST00000296302 / NM_001366071.2; = p.E1501K on NM_018313.5) | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- RNF6 | c.1808T>A p.I603K | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHISAL2A | c.436A>C p.S146R | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.136); called by muse, mutect2
- SP3 | c.113A>T p.Q38L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- STXBP4 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 36/223 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- TAS2R20 | c.382G>A p.V128I | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- TBX3 | c.1835C>T p.A612V (on ENST00000257566 / NM_016569.4; = p.A592V on NM_005996.4) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- BCLAF3 | c.990G>A p.G330= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV61414873; called by muse, mutect2, varscan2
- C12orf56 | c.717T>C p.I239= | Silent (SNP) | VAF 18/124 reads (15%) | called by muse, mutect2, varscan2
- DAPK1 | c.3921C>A p.L1307= | Silent (SNP) | VAF 40/232 reads (17%) | catalogued as COSV100803011; called by muse, mutect2, varscan2
- DIS3L | c.2631C>T p.D877= (on ENST00000319212 / NM_001143688.3; = p.D794= on NM_133375.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as rs373138447; called by muse, mutect2, varscan2
- IGHV2-70D | c.237C>T p.F79= | Silent (SNP) | VAF 24/96 reads (25%) | called by muse, varscan2
- IGHV2-70D | c.225T>C p.D75= | Silent (SNP) | VAF 24/104 reads (23%) | called by muse, varscan2
- IGLC2 | c.195G>A p.K65= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs1803804; called by muse, mutect2
- LDB3 | c.564C>T p.G188= | Silent (SNP) | VAF 15/105 reads (14%) | catalogued as rs753281302; called by muse, mutect2, varscan2
- MAN1B1 | c.1944G>A p.Q648= | Silent (SNP) | VAF 16/87 reads (18%) | called by muse, mutect2, varscan2
- MCHR1 | c.891C>T p.Y297= | Silent (SNP) | VAF 26/112 reads (23%) | catalogued as rs371275583; called by muse, mutect2, varscan2
- ZBTB45 | c.570T>C p.A190= | Silent (SNP) | VAF 11/48 reads (23%) | called by muse, mutect2, varscan2
- ANKRD26P1 | n.465C>G | RNA (SNP) | VAF 36/241 reads (15%) | called by muse, mutect2, varscan2
- ARMH4 | c.*1982A>C | 3'UTR (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- ATXN2 | c.3913+221C>T | Intron (SNP) | VAF 28/157 reads (18%) | called by muse, mutect2, varscan2
- FBLN7 | c.670+85C>T | Intron (SNP) | VAF 10/71 reads (14%) | called by muse, mutect2, varscan2
- FGF11 | c.193+27C>T | Intron (SNP) | VAF 14/70 reads (20%) | catalogued as rs1358582917; called by muse, mutect2, varscan2
- ITGAL | c.445+53G>T | Intron (SNP) | VAF 25/135 reads (19%) | called by muse, mutect2, varscan2
- KLHL13 | c.99-145A>G | Intron (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2
- LNPEP | c.*8654T>A | 3'UTR (SNP) | VAF 10/77 reads (13%) | called by muse, mutect2, varscan2
- PARP16 | c.-411C>T | 5'UTR (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- PEAK1 | c.*5560G>A | 3'UTR (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- PGAP1 | c.*4594C>T | 3'UTR (SNP) | VAF 10/57 reads (18%) | called by muse, mutect2, varscan2
- PLEKHF2 | c.*92T>C | 3'UTR (SNP) | VAF 40/174 reads (23%) | called by muse, mutect2, varscan2
- TACC1 | c.*3342_*3343del | 3'UTR (DEL) | VAF 13/68 reads (19%) | called by mutect2, pindel, varscan2
